Somatic mutation profile of tumor specimen TCGA-XV-AAZY-01A (aliquot TCGA-XV-AAZY-01A-12D-A401-08) from TCGA case TCGA-XV-AAZY, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 76.5 years (27,938 days).
Specimen TCGA-XV-AAZY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5639a813-e59d-4543-9424-cb36b1ce6a6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XV-AAZY-10A (Blood Derived Normal), aliquot TCGA-XV-AAZY-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d45f092e-c53f-40e5-81b2-19b0e9ee159c

The open-access MAF lists 203 somatic variants for this specimen: 133 protein-altering or splice-affecting, 67 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 67, Nonsense Mutation 8, Translation Start Site 2, Splice Region 2, Intron 2, Splice Site 1, Frame Shift Del 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 62/132 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.1617G>A p.W539* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99559532; called by muse, mutect2, varscan2
- AC244197.3 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CM990746, COSV100558118; called by muse, mutect2, varscan2
- ADAM7 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV51546060; called by muse, mutect2, varscan2
- ADCYAP1 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52487617; called by muse, mutect2
- ADGRD1 | c.1469G>A p.R490K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99896487; called by muse, mutect2
- ANK3 | c.4102G>A p.D1368N (on ENST00000280772 / NM_001320874.2; = p.D502N on NM_001149.3) | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99781462; called by muse, mutect2, varscan2
- AP3M1 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as rs372550482; called by muse, mutect2, varscan2
- AQR | c.1805A>G p.D602G | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.538); catalogued as COSV99334384; called by muse, mutect2, varscan2
- ARHGAP31 | c.4091C>T p.S1364F | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99957487; called by muse, mutect2, varscan2
- ATP5MC1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100582403; called by muse, mutect2, varscan2
- C2orf16 | c.2927G>A p.R976K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs768214000, COSV62677559; called by muse, mutect2, varscan2
- CACNA1E | c.4955C>T p.S1652F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1485187097, COSV100704373; called by muse, mutect2
- CCDC178 | c.102G>A p.W34* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100285969; called by muse, mutect2
- CCDC47 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99854277; called by muse, mutect2, varscan2
- CD163 | c.3257G>A p.R1086K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.237); catalogued as COSV100776022; called by muse, mutect2, varscan2
- CDC14A | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV100325650; called by muse, mutect2, varscan2
- CNBD2 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV62586946; called by muse, mutect2, varscan2
- CNBD2 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV100839144; called by muse, mutect2, varscan2
- COL17A1 | c.1223-1G>A p.X408_splice | Splice Site (SNP) | VAF 14/83 reads (17%) | catalogued as COSV100793265; called by muse, mutect2, varscan2
- COL19A1 | c.2669G>A p.G890E | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59587181; called by muse, mutect2, varscan2
- COL6A3 | c.6293G>A p.G2098E | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1310904, COSV99800195; called by muse, mutect2, varscan2
- CRYGD | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100006105; called by muse, mutect2, varscan2
- CSH2 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs779474596, COSV100400300; called by mutect2, varscan2
- CXCR4 | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.272); catalogued as rs1344271734, COSV99603305; called by muse, mutect2
- DAP3 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100546624; called by muse, mutect2, varscan2
- DGKI | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | catalogued as rs1259961080, COSV55934682; called by muse, mutect2
- DNAH5 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as COSV99452383; called by muse, mutect2, varscan2
- DOC2A | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100451344; called by muse, mutect2, varscan2
- DUOX1 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99973413; called by muse, mutect2, varscan2
- DYM | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.695); catalogued as rs769667648, COSV53989853, COSV53992855; called by muse, mutect2, varscan2
- DYRK1A | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs1555987037, COSV100118158; called by muse, mutect2, varscan2
- DYRK4 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99157367; called by muse, mutect2, varscan2
- ENPP3 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as rs371138539; called by muse, mutect2
- EPPIN | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs915255610, COSV60549148; called by muse, mutect2, varscan2
- ERICH6 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99901868; called by muse, mutect2, varscan2
- FBXO38 | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs1172459945, COSV99693777; called by muse, mutect2, varscan2
- FBXW12 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56483901; called by muse, mutect2, varscan2
- FGD6 | c.18G>A p.E6= | Splice Region (SNP) | VAF 12/59 reads (20%) | catalogued as rs750051583, COSV100676734; called by muse, mutect2, varscan2
- FLNA | c.6983C>T p.P2328L (on ENST00000369850 / NM_001110556.2; = p.P2320L on NM_001456.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs782310851, COSV100774982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GDA | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV99429590; called by muse, mutect2, varscan2
- GLDN | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100117941; called by muse, mutect2, varscan2
- GLUD2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.722); catalogued as COSV100047004; called by muse, mutect2, varscan2
- GON4L | c.5569G>A p.G1857R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99675255; called by muse, mutect2, varscan2
- GPR119 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52276338; called by muse, mutect2, varscan2
- HDAC3 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59495962; called by muse, mutect2, varscan2
- HENMT1 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs771530768, COSV64230874; called by muse, mutect2, varscan2
- HOXC11 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.102); catalogued as COSV99678484; called by muse, varscan2
- IL36B | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs267598838, COSV52084862; called by muse, mutect2, varscan2
- KEL | c.1203G>A p.M401I | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV62338376; called by muse, mutect2, varscan2
- KIAA0232 | c.3325C>T p.R1109C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160781082, COSV56924062; called by muse, mutect2, varscan2
- LAMB4 | c.4993G>A p.E1665K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs753900276, COSV99225004; called by muse, mutect2, varscan2
- LCA5L | c.1208C>A p.T403N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.272); catalogued as COSV99903802; called by muse, mutect2, varscan2
- LRP1 | c.5634C>G p.S1878R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.979); catalogued as COSV99676692; called by muse, mutect2
- LRP1 | c.10369C>T p.Q3457* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99676694; called by muse, mutect2, varscan2
- LRRK2 | c.3428C>T p.S1143F | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV100110873; called by muse, mutect2, varscan2
- MAP11 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs1312097944, COSV100385586; called by muse, mutect2, varscan2
- METTL21C | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767705244, COSV99940112; called by muse, mutect2, varscan2
- MUC16 | c.18401C>T p.S6134L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV67447839; called by muse, mutect2, varscan2
- MUC16 | c.3023C>T p.S1008F | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67479488; called by muse, mutect2, varscan2
- MYLK3 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.401); catalogued as rs1325989776, COSV101189172; called by muse, mutect2, varscan2
- NCOA1 | c.3715C>T p.P1239S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV56040850; called by muse, mutect2, varscan2
- NCR3 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as COSV53002449; called by muse, mutect2, varscan2
- NDST4 | c.1068G>A p.G356= | Splice Region (SNP) | VAF 7/28 reads (25%) | catalogued as rs1175255305, COSV99997367; called by muse, mutect2, varscan2
- NOL4 | c.1678G>A p.G560R | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); catalogued as COSV52361472, COSV99307795; called by muse, mutect2, varscan2
- NUFIP1 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV100998039; called by muse, mutect2, varscan2
- NUP210L | c.3216C>A p.Y1072* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as rs762599582, COSV99668676; called by muse, mutect2, varscan2
- NWD1 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as COSV100343361; called by muse, mutect2, varscan2
- OR1A1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs371610534; called by muse, mutect2, varscan2
- OR2A2 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as rs770732468, COSV101286664; called by muse, mutect2, varscan2
- OR51A4 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV66749251; called by muse, mutect2, varscan2
- OR56B1 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100402686; called by muse, mutect2, varscan2
- OR5AS1 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV100546336, COSV57981766; called by muse, mutect2, varscan2
- OR5AU1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); catalogued as COSV100436183; called by muse, mutect2, varscan2
- OR5D18 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as rs1378344115, COSV61738330; called by muse, mutect2, varscan2
- OR5M11 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV101602056; called by muse, mutect2, varscan2
- OR6C70 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1229572364, COSV100524465; called by muse, mutect2, varscan2
- OR9K2 | c.353C>T p.S118F (on ENST00000305377; = p.S96F on NM_001005243.1) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59531381; called by muse, mutect2, varscan2
- OSBPL5 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV99720645; called by muse, mutect2
- OSBPL8 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99675416; called by muse, mutect2, varscan2
- P2RY10 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99409262; called by muse, mutect2, varscan2
- P4HA2 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as rs267600343, COSV99386887, COSV99387242; called by muse, mutect2, varscan2
- PCDHGC5 | c.1244A>T p.E415V | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99341495; called by muse, mutect2, varscan2
- PDIA4 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV53723311; called by muse, mutect2, varscan2
- PIK3IP1 | c.680C>T p.T227I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV99314156; called by muse, mutect2, varscan2
- PIM2 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV99332167; called by muse, mutect2, varscan2
- PKHD1L1 | c.10538C>T p.P3513L | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV101006621; called by muse, mutect2, varscan2
- POMGNT2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 7/13 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.746); catalogued as COSV100768124; called by muse, mutect2, varscan2
- POTEM | c.940T>A p.C314S | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.329); catalogued as rs1394704291; called by muse, mutect2, varscan2
- PRDM2 | c.1892G>A p.S631N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.074); catalogued as COSV99342398; called by muse, mutect2
- PRDM9 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV99690907; called by muse, mutect2, varscan2
- PRL | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs1194537408, COSV100123123; called by muse, mutect2, varscan2
- PROX1 | c.1706C>T p.S569L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs138867261, COSV54777163; called by muse, mutect2, varscan2
- PTCH2 | c.3052C>T p.P1018S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100942223; called by muse, mutect2, varscan2
- PTPRB | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV54255799; called by muse, mutect2, varscan2
- PTPRR | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV51728591; called by muse, mutect2, varscan2
- PZP | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs765795584, COSV99738859; called by muse, mutect2, varscan2
- RARB | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs764694971; called by muse, mutect2, varscan2
- RASGRF1 | c.1776G>A p.M592I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV101369728; called by muse, mutect2, varscan2
- RORC | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs199550478, COSV59092062; called by muse, mutect2, varscan2
- SEC63 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100938444; called by muse, mutect2, varscan2
- SEC63 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100938445; called by muse, mutect2, varscan2
- SLC39A10 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100660717; called by muse, mutect2, varscan2
- SLC8A3 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100776308; called by muse, mutect2, varscan2
- SLIT1 | c.3283G>A p.G1095R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99822113; called by muse, mutect2
- SMG1 | c.5575C>T p.P1859S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs756261490, COSV67175253; called by muse, mutect2
- SNX14 | c.2365G>A p.G789R (on ENST00000314673 / NM_001350535.1; = p.G736R on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100121712; called by muse, mutect2, varscan2
- SPANXN2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 114/534 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs200779971, COSV100979954; called by muse, varscan2
- SPATA12 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.432); catalogued as COSV100534711; called by muse, mutect2, varscan2
- SPRY3 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100249464; called by muse, mutect2, varscan2
- SPTY2D1 | c.1973T>G p.L658R | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100311776; called by muse, mutect2, varscan2
- ST6GAL2 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 13/81 reads (16%) | PolyPhen benign (0.062); catalogued as COSV64527521; called by muse, mutect2, varscan2
- STC2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.494); catalogued as rs1256709561, COSV54182068; called by muse, mutect2, varscan2
- SYT1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs138582600, COSV54034805; called by muse, mutect2, varscan2
- TAS2R40 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.015); catalogued as COSV101283017; called by muse, mutect2, varscan2
- TBCCD1 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100112074; called by muse, mutect2, varscan2
- TMEM132D | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.203); catalogued as rs767399445, COSV101242860; called by muse, mutect2, varscan2
- TNC | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100406096; called by muse, mutect2, varscan2
- TNXB | c.10808C>T p.P3603L (on ENST00000647633; = p.P3356L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1162946901, COSV64484940; called by muse, mutect2, varscan2
- TNXB | c.3805C>T p.P1269S (on ENST00000647633; = p.P1022S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV100926493; called by muse, mutect2, varscan2
- TOX2 | c.238C>T p.P80S (on ENST00000358131 / NM_001098798.2; = p.P29S on NM_032883.3) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100364401; called by muse, mutect2, varscan2
- TRIM25 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100381066; called by muse, mutect2
- TSPO2 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV55112486; called by muse, mutect2, varscan2
- TTN | c.14575G>A p.D4859N (on ENST00000591111; = p.D3932N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | PolyPhen benign (0.003); catalogued as COSV60001937, COSV60184417; called by muse, mutect2, varscan2
- WBP1L | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as rs528315445, COSV100882488; called by muse, mutect2, varscan2
- WDR49 | c.1627G>A p.E543K (on ENST00000308378 / NM_001366158.1; = p.E884K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs867011458, COSV57706145; called by muse, mutect2, varscan2
- ZFP1 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.711); catalogued as rs752555340, COSV100182132; called by muse, mutect2, varscan2
- ZGRF1 | c.3662C>T p.S1221L | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376820149; called by muse, mutect2, varscan2
- ZIC3 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54972312, COSV99799302; called by muse, mutect2, varscan2
- ZNF646 | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100336806; called by muse, mutect2
- HEATR3 | c.1648_1656del p.S550_N552del | In Frame Del (DEL) | VAF 9/71 reads (13%) | called by mutect2, pindel, varscan2
- MUC2 | c.541T>C p.S181P | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.18); called by muse, mutect2, varscan2
- SRRM2 | c.4462_4469del p.A1488Sfs*4 | Frame Shift Del (DEL) | VAF 31/150 reads (21%) | called by mutect2, pindel, varscan2
- ABCD1 | c.1776G>A p.E592= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV99497659, COSV99497814; called by muse, mutect2, varscan2
- AC097636.1 | c.159G>A p.L53= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV101469685; called by muse, mutect2
- ADORA2A | c.1149G>A p.V383= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100418105; called by muse, mutect2
- AFF3 | c.3036C>T p.I1012= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as rs773934210, COSV57840344; called by muse, mutect2, varscan2
- ANK3 | c.13086G>A p.V4362= (on ENST00000280772 / NM_001320874.2; = p.V986= on NM_001149.3) | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as rs768776250, COSV55073254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO4 | c.2064G>A p.R688= (on ENST00000392977 / NM_001286615.2; = p.R653= on NM_178826.4) | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs1403569410, COSV100153464; called by muse, mutect2, varscan2
- APOB | c.7329C>T p.I2443= | Silent (SNP) | VAF 34/149 reads (23%) | catalogued as COSV99266999; called by muse, mutect2, varscan2
- ARHGAP4 | c.1482C>T p.P494= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV63132987; called by muse, mutect2, varscan2
- ASIC4 | c.438C>T p.D146= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100761880; called by muse, mutect2, varscan2
- ATM | c.4785C>T p.N1595= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV99590970; called by muse, mutect2, varscan2
- BMT2 | c.321C>T p.F107= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV51776339, COSV99774772; called by muse, mutect2, varscan2
- CALCR | c.876C>T p.I292= (on ENST00000649521 / NM_001164737.2; = p.I276= on NM_001742.4) | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100810738; called by muse, mutect2, varscan2
- CDH10 | c.1263C>T p.S421= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100052533; called by muse, mutect2, varscan2
- CHST5 | c.109C>T p.L37= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1363543763, COSV100292074; called by muse, mutect2, varscan2
- CTNNA2 | c.1335G>A p.V445= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100561621; called by muse, mutect2, varscan2
- CTSG | c.564G>A p.G188= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1231935403, COSV99361645; called by muse, mutect2
- DBF4B | c.1536C>T p.P512= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100154625; called by muse, mutect2, varscan2
- DNAH9 | c.7287C>T p.F2429= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs745641624, COSV99307202; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1692C>T p.F564= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs1433122404, COSV62568492, COSV62568976; called by muse, mutect2, varscan2
- FAM151B | c.327T>G p.V109= | Silent (SNP) | VAF 20/220 reads (9%) | catalogued as COSV99971821; called by muse, mutect2
- FSIP2 | c.19764G>A p.K6588= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100555852; called by muse, mutect2, varscan2
- GAS7 | c.609C>T p.Y203= (on ENST00000432992 / NM_201433.2; = p.Y63= on NM_003644.3) | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100096434; called by muse, mutect2
- GHRHR | c.999C>T p.F333= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100396712; called by muse, mutect2, varscan2
- GPR176 | c.180C>T p.F60= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100137386; called by muse, mutect2, varscan2
- HNRNPUL1 | c.549C>T p.Y183= | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as COSV99647482; called by muse, mutect2, varscan2
- HOXC11 | c.507C>T p.P169= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV54533892; called by muse, mutect2, varscan2
- IFNW1 | c.183C>T p.F61= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs748935849, COSV101207633; called by muse, mutect2, varscan2
- ITGA11 | c.1038G>A p.G346= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV59880580; called by muse, mutect2, varscan2
- KCNA6 | c.351C>T p.F117= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs1161020106, COSV54974317; called by muse, mutect2, varscan2
- KCNK2 | c.552C>T p.L184= (on ENST00000444842 / NM_001017425.3; = p.L169= on NM_014217.4) | Silent (SNP) | VAF 40/78 reads (51%) | catalogued as COSV101222278; called by muse, mutect2, varscan2
- LAG3 | c.102C>T p.A34= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99179977; called by muse, varscan2
- LCE1A | c.66C>T p.P22= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV100632112; called by muse, mutect2, varscan2
- LDOC1 | c.228C>T p.L76= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as COSV65159458; called by muse, mutect2, varscan2
- LTA | c.63T>G p.L21= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV101403242; called by muse, mutect2, varscan2
- MED1 | c.2064G>A p.K688= | Silent (SNP) | VAF 43/150 reads (29%) | catalogued as COSV100328047; called by muse, mutect2, varscan2
- MERTK | c.2538C>T p.T846= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV54925455; called by muse, mutect2, varscan2
- MTMR8 | c.966C>T p.F322= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV66395604; called by muse, mutect2, varscan2
- MYH11 | c.735C>T p.F245= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV55552560; called by muse, mutect2, varscan2
- MYH3 | c.2949C>T p.L983= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV99878613; called by muse, mutect2, varscan2
- NLRC5 | c.783C>T p.F261= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs768417275, COSV99347893; called by muse, mutect2, varscan2
- NRXN3 | c.480C>T p.S160= (on ENST00000557594 / NM_001272020.2; = p.S792= on NM_004796.6) | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV99820757; called by muse, mutect2, varscan2
- OR5AK2 | c.822C>T p.A274= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100476091; called by muse, mutect2, varscan2
- OR8D4 | c.171C>T p.T57= | Silent (SNP) | VAF 22/144 reads (15%) | catalogued as COSV100361687; called by muse, mutect2, varscan2
- OSBPL10 | c.1335C>T p.I445= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV101159727; called by muse, mutect2, varscan2
- PAPPA2 | c.1554C>T p.P518= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs553799926, COSV100866963; called by muse, mutect2, varscan2
- PCDH15 | c.5722C>T p.L1908= | Silent (SNP) | VAF 34/152 reads (22%) | catalogued as COSV100225246, COSV57303725; called by muse, mutect2, varscan2
- PCDHGC5 | c.1245G>A p.E415= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as COSV99341497; called by muse, mutect2, varscan2
- PHKA1 | c.414C>T p.T138= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100263691; called by muse, mutect2, varscan2
- PHKA2 | c.3573C>T p.D1191= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV101177307; called by muse, mutect2, varscan2
- PPP1R12C | c.2328C>T p.V776= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV99136834; called by muse, mutect2
- PRIMPOL | c.1446T>C p.D482= | Silent (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- PROM1 | c.12A>G p.V4= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV101477117; called by muse, mutect2
- RBM25 | c.60G>A p.G20= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99998595, COSV99998910; called by muse, mutect2, varscan2
- RFX6 | c.1486C>T p.L496= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV100263747, COSV60583497; called by muse, mutect2, varscan2
- RUBCNL | c.1611G>A p.K537= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100529275; called by muse, mutect2, varscan2
- RYR3 | c.3726G>A p.P1242= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs765747906, COSV101211957; called by muse, mutect2, varscan2
- SDF2 | c.219G>A p.R73= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV99897967; called by muse, mutect2, varscan2
- SGMS1 | c.1017C>T p.I339= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV100693589; called by muse, mutect2, varscan2
- SI | c.4623C>T p.L1541= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as COSV100014417, COSV100016601, COSV52266243; called by muse, mutect2, varscan2
- SPTBN2 | c.2934C>A p.T978= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100020080; called by muse, mutect2, varscan2
- TMEM116 | c.276C>T p.F92= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100702247; called by muse, mutect2, varscan2
- TMIGD1 | c.555C>T p.V185= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as rs1483181140, COSV100187330; called by muse, mutect2, varscan2
- TSHR | c.1809G>A p.K603= | Silent (SNP) | VAF 50/204 reads (25%) | catalogued as COSV99992456; called by muse, mutect2, varscan2
- USP32 | c.4584C>T p.V1528= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV100342563; called by muse, mutect2, varscan2
- ZBED1 | c.1353C>T p.I451= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as rs1476618104, COSV100585910; called by muse, mutect2, varscan2
- ZDBF2 | c.315G>A p.E105= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100985240; called by muse, mutect2, varscan2
- ZNF14 | c.1452C>T p.F484= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV100694113; called by muse, mutect2, varscan2
- MIR527 | n.51G>A | RNA (SNP) | VAF 38/166 reads (23%) | called by muse, mutect2, varscan2
- MOG | c.593-75G>A | Intron (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100971934; called by muse, mutect2, varscan2
- SYT1 | c.929-24760C>T | Intron (SNP) | VAF 12/58 reads (21%) | catalogued as rs758584383, COSV99696746; called by muse, mutect2, varscan2
